Somatic mutation profile of tumor specimen TCGA-DJ-A2Q5-01A (aliquot TCGA-DJ-A2Q5-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2Q5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 51.3 years (18,727 days).
Specimen TCGA-DJ-A2Q5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1ba9a52-5b91-48d3-ac5e-0dd29f898df4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q5-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q5-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/725f0dc3-962b-4e53-b548-28020ee6cbb4

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- CTTNBP2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50390708; called by muse, mutect2, varscan2
- DLG1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV58378550; called by muse, mutect2
- ITPR2 | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs755273881, COSV67265647, COSV67270256; called by muse, mutect2, varscan2
- TRPC7 | c.1696G>T p.G566W | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61453714; called by muse, mutect2
